Somatic mutation profile of tumor specimen TCGA-EL-A3N3-01A (aliquot TCGA-EL-A3N3-01A-11D-A20C-08) from TCGA case TCGA-EL-A3N3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 53.4 years (19,513 days).
Specimen TCGA-EL-A3N3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c6910e7-71f2-407d-9f5f-2811e383121b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3N3-11A (Solid Tissue Normal), aliquot TCGA-EL-A3N3-11A-11D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/185da023-64fa-4148-ac54-12962edff51d

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BOLL | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV56574089; called by muse, mutect2, varscan2
- CENPW | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as COSV64176892; called by muse, mutect2, varscan2
- DTX1 | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV55655083, COSV55655407; called by muse, mutect2, varscan2
- LGI3 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV60443246; called by muse, mutect2, varscan2
- MAGEE2 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV64897576; called by muse, mutect2, varscan2
- MDN1 | c.12883A>T p.M4295L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV65520629; called by muse, mutect2, varscan2
- SYNE1 | c.18604G>T p.V6202F (on ENST00000367255 / NM_182961.4; = p.V6131F on NM_033071.3) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV54962450; called by muse, mutect2, varscan2
- TCF7L1 | c.1069A>T p.M357L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56397971; called by muse, mutect2, varscan2
- TENM2 | c.5408T>C p.I1803T (on ENST00000518659 / NM_001122679.2; = p.I1564T on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs6859235, COSV69128169; called by muse, mutect2, varscan2
- CHD5 | c.2988C>G p.P996= | Silent (SNP) | VAF 93/322 reads (29%) | catalogued as COSV52412844; called by muse, mutect2, varscan2
- MYLK | c.2436G>A p.Q812= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as COSV60608896; called by muse, mutect2, varscan2
- RASAL1 | c.1950C>T p.T650= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55655415; called by muse, mutect2, varscan2
